Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6224, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6224-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Nck: left neck contents - Level I
2. Neck: Left neck contents - Level II
3. Neck: Left neck contents - Level IV
4. Neck: Left neck contents - Level III
5. Oral Cavity: Hemiglossectomy
6. Soft Tissue: Left posterior margin
7. Soft Tissue: Left lateral margin
8. Soft Tissue: Medial margin
9. Oral Cavity: Revision glossectomy
10. Surgical Waste

Diagnosis

1. Left neck; level I:
- Six lymph nodes, negative for malignancy (0/6).
- Submandibular gland with no pathologic changes.
2. Left neck; level II:
- Metastatic squamous cell carcinoma involving two of thirteen lymph nodes (2/13).
- a. Largest involved lymph node measures 1.6 cm.
- b. Extracapsular extension is present.
3. Left neck; level IV:
- Eight lymph nodes, negative for malignancy (0/8).
4. Left neck; level III:
- Metastatic squamous cell carcinoma involving one of two lymph nodes (1/2).
- a. Involved node measures 1.7 cm.
- b. Extracapsular extension is present.
5. Left hemiglossectomy:
- Squamous cell carcinoma, poorly differentiated.
- a. Maximum tumour dimension 3.3 cm.
- b. Maximum tumour thickness 1.0 cm.

[page 2 of 4]
- c. Perineural invasion is present.
- d. Tumour is close (0.3 cm) to inferior floor of mouth and deep margins.
- e. All other margins are negative for malignancy (> 0.5 cm).

6. Left posterior margin:
- Negative for malignancy.

7. Left lateral margin:
- Negative for malignancy.

8. Medial margin:
- Negative for malignancy.

9. Revision glossectomy:
- Skeletal muscle, negative for malignancy.

10. Surgical waste:
- Skin and fibroadipose tissue with no pathologic abnormality (gross examination only).

Synoptic Data

Specimen Type:	Resection: Left hemiglossectomy.
Tumor Site:	Tongue
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 3.3 cm Tumor thickness: 1.0 cm
Histologic Grade:	G3: Poorly differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Margins:	Margins uninvolved by tumor Margins uninvolved by tumor - Distance of tumor from closest margin: 0.3 cm Margins: Inferior floor of mouth and deep margins.
Pathologic Staging (pTNM):	pT2: Tumor of lip or oral cavity more than 2 cm but not more than 4 cm in greatest dimension pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx Number of regional lymph nodes examined: 29 Number of regional lymph nodes involved: 3 Extra-capsular extension of nodal tumor: Present pMX: Distant metastasis cannot be assessed

Electronically

Gross Description

[page 3 of 4]
1. The specimen is labeled with the patient's name and "left neck contents level I". It consists of portion of fibroadipose tissue measuring 6.3 x 3.6 x 3.2 cm. a grossly unremarkable submandibular gland is identified measuring 4.4 x 3.5 x 2.8 cm. Multiple lymph nodes ranging from 0.6 x 0.5 x 0.4 to 1.4 x 0.8 x 0.6 cm are identified. Representative sections are submitted.

1A submandibular gland
1B one lymph node bisected
1C multiple lymph nodes
1D two lymph nodes

2. The specimen is labeled with the patient's name and "left neck contents level II". It consists of portion of fibroadipose tissue measuring 4.3 x 2.2 x 1.6 cm. Multiple lymph nodes ranging from 0.4 x 0.4 x 0.3 to 1.6 x 0.7 x 0.7 cm are identified. Representative sections are submitted.

2A one lymph node bisected
2B multiple lymph nodes
2C multiple lymph nodes
2D one lymph node bisected
2E one lymph node bisected

3. The specimen is labeled with the patient's name and "left neck contents level IV". It consists of portion of fibroadipose tissue measuring 3.2 x 1.5 x 1.3 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1.6 x 0.5 x 0.4 cm are identified. Representative sections are submitted.

3A one lymph node bisected
3B multiple lymph nodes
3C multiple lymph nodes

4. The specimen is labeled with the patient's name and "left neck contents level III". It consists of portion of fibroadipose tissue measuring 6.4 x 2.5 x 1.3 cm. two lymph nodes measuring 0.9 x 0.6 x 0.5 and 1.7 x 0.6 x 0.5 cm are identified. Representative sections are submitted.

4A one lymph node bisected
4D one lymph node bisected

5. The specimen is labeled the patient's name and as "left hemiglossectomy". It consists of a portion of left tongue measuring 3.4 SI x 2.5 ML x 7.0 cm AP cm. The specimen is oriented by the surgeon. There is an ill defined ulcerated brown-tan tumor involving the lateral surface of the tongue. The tumor measures 2.5 SI x 1.0 ML x 3.3 AP cm. It is located at 0.3 cm from the deep soft tissue margin, 1.3 cm away cm from the medial/superior tongue margin, 1.7 cm from the anterior tongue margin, 1.7 from the posterior tongue margin and is 0.8 cm away from the inferior floor of mouth margin. The remaining tongue mucosa is grossly unremarkable.

The deep/medial soft tissue margin is painted with India ink and the posterior margin is painted with green dye. A representative section of the tumor including deep soft tissue margin is examined at intraoperative consultation. Representative sections are submitted.

5A frozen section resubmitted
5B. anterior tongue margin
5C posterior tongue margin
5D inferior floor of mouth margin
5E tumor including superior tongue margin
5F tumor including inferior floor of mouth margin
5G. representative section tumor
three pieces of tumor and two pieces of normal patients taken for tissue banking

[page 4 of 4]
6. The specimen is labeled with the patient's name and as "left posterior margin [REDACTED]". It consists of a fragment of tissue measuring 1.4 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

7 The specimen is labeled with the patient's name and as "left lateral margin". It consists of a fragment of tissue measuring 1.5 x 0.4 x 0.2 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "medial margin". It consists of a fragment of tissue measuring 2.5 x 0.4 x 0.5 cm. The specimen is submitted in toto for frozen section.

8A frozen section control

9. The specimen is labeled the patient's name and as "revision glossectomy" It consists of a portion of unoriented grossly unremarkable tongue measuring 1.5 x 0.5 x 0.4 cm. The margins are painted with ink.

9A specimen serially sectioned and submitted in toto

10. The specimen container is labeled with the patient's name and as "surgical waste". Multiple pieces of unoriented tan skin with underlying fibroadipose tissue received in 10% buffered formalin. The tissue ranges in size from 1.5 x 0.5 x 0.6 cm to 5.5 x 3.8 x 0.3 cm. No gross abnormalities are noted. No tissue submitted for histologic examination.

[REDACTED]
Quick Section Diagnosis

5A: Left hemiglossectomy deep margin: Deep margin is close (0.3 cm) to tumour but negative.

Spoke to surgeon in person at [REDACTED]

6A-8A: Margins (left posterior, left lateral, medial): Negative for malignancy.

Called at [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file a673578a-9523-4483-bc27-1062999256ef (TCGA-CQ-6224.219A3DA1-9AA2-4CD9-AA79-BF94D0975E4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).